Surgical pathology report (de-identified scan), TCGA case TCGA-5M-AAT4, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Sao Paulo, specimen TCGA-5M-AAT4-01A (Primary Tumor).

Date:

SPECIMEN: terminal ileum, cecum, right colon, appendix and transverse colon.

PROCEDURE: Right hemicolectomy with distal ileostomy

MACROSCOPY

- Segment of right and transverse colons, opened along its longitudinal axis, with cecum, appendix, and terminal ileum.
- Appendix shows 4.0 cm of length and 0.7 cm of diameter.
- The right and transverse colons measure 22.0 cm of length and 1.5 cm of mean diameter.
- A vegetating tumor with elevated infiltrative borders and central ulceration, measuring 5.0 x 4.0 cm is found in the colonic mucosa 6.5 cm from the nearest surgical margin.
- Three lymph nodes are grossly identified in the 12.0 x 11.5 cm area of pericolic fat tissue.
- The adjacent mucosa is pale and shows three 0.9 cm polyps each near the ileocecal valve.

MICROSCOPIC EXAMINATION

- Moderately differentiated tubular adenocarcinoma of the right colon.
- Microscopic tumor extension: tumor invades until the fat subserosa.
- Lymph-vascular invasion: present.
- Surgical margins free of neoplasia.
- Moderate peritumoral lymphocytic infiltrate.
- Moderate stromal desmoplasia.
- Extensive areas of necrosis in the tumor.
- Number of lymph nodes examined: 3.
- Number of lymph nodes positive for neoplasia: 0.
- Adjacent intestinal mucosa with one villous adenoma with high grade epithelial dysplasia, and two polyps with low grade epithelial dysplasia.
- Appendix displays no pathologic features.
- Stage (TNM 7th edition): pT3 pN0 pMx.

PATHOLOGISTS

CHE *ICD-O-3*
Adenocarcinoma NOS 8140/3

path
Adenocarcinoma, tubular 8211/3

CHE
Site: Ascending colon C18.2

path
Right colon C18.2

JS 5/21/14

Source: NCI Genomic Data Commons file 473411dc-c722-42ca-beec-d8645f7a4acd (TCGA-5M-AAT4.C0BABB5A-B0ED-42A6-A9D1-6B26843A375D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).